Gene-level copy-number profile of tumor specimen TCGA-G2-AA3D-01A from TCGA case TCGA-G2-AA3D, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.8 years (22,205 days).
Specimen TCGA-G2-AA3D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e22d0457-c96f-440c-9e37-a958e1e41b3f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-AA3D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e1954f9-8075-4f1f-a7d9-ce4fddaf779c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 427; copy number 2: 8,960; copy number 3: 16,383; copy number 4: 21,927; copy number 5: 8,860; copy number 6: 2,561; copy number 7: 96; copy number 8: 193; copy number 9: 174; copy number 10: 206.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-AA3D-01A-11D-A390-01): tumor purity 0.69, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–2): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr12:26,301,098–26,833,194, 6 genes (within-gene range 0–2): AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354.
- chr14:67,819,779–68,730,218, 5 genes (within-gene range 0–3): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 380 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:46,469,341–49,857,919, 79 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr16:70,523,791–74,306,288, 95 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr16:84,476,355–84,554,033, 1 gene, copy number 10 (within-gene range 6–10): MEAK7.
- chr16:84,565,596–90,222,851, 205 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
